Surgical pathology report (de-identified scan), TCGA case TCGA-36-2540, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2540-01A (Primary Tumor).

[page 1 of 5]
TCGA - 36 - 2540

gical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

Omentectomy, hysterectomy, bilateral salpingo-oophorectomy, terminal ileum/cecum resection and partial colonic resection:

1. Extensive low-grade serous carcinoma (low mitotic rate; low to intermediate grade nuclei; papillary to micropapillary architecture, numerous psammoma bodies)
2. Involvement of right ovary (5 mm deposit); left ovary (small 3 mm surface deposit) to small deposits on the external aspects of adventitia/paratubal tissue of right and left fallopian tube and broad ligaments, uterine serosa including cul de sac (note that the separately submitted cul de sac cyst is endosalpingiitic), bulky omental deposits, bulky serosa and subserosal deposits adjacent to terminal ileum, cecum and separately submitted colon segment-in the latter there is invasion into the muscularis propria and involvement of the soft tissue dissection plane. Largest single tumour deposit 7 cm maximal dimension (omentum).
3. No recognizable background serous borderline neoplasia
4. Three of eight lymph nodes in mesenteries of colon positive for microscopic tumour deposits (largest 3 mm-see diagnostic comment)
5. Uterus internally shows mass forming uterine adenomyosis/adenomyoma; nondysplastic endocervix/ectocervix with benign non-hyperplastic proliferative endometrium
6. Concomitant endometriosis-quite extensive serosal deposits thereof, uterus and adnexae

[page 2 of 5]
Final Diagnosis Comment:

The exact origin of this low-grade serous carcinoma is unclear. The bulk of the neoplasm is extrapelvic with the ovarian involvement minor compared to the omental and pericolonic/peri-ileal involvement. All tumour deposits including those in the right ovary and tube, exhibit significant surface involvement.

I suspect that this carcinoma is primary peritoneal derived. The fallopian tubes do not harbour internal carcinoma. One lymph node in the pericecal fat and two lymph nodes in the pericolonic fat are positive for tumour deposit. The involvement of these lymph nodes indicates access to the intestinal lymphatic flow towards the liver. These are not strictly N1 nodes.

Clinical History as Provided by Submitting Physician:

- A. Omentum
- B. R ovary and tube
- C. L ovary and tube
- D. Uterus and cervix
- E. Cul-de-sac
- F. Terminal ileum and cecum
- G. Colon

Specimens Received:

- A: omentum
- B: right ovary + tube
- C: left ovary + tube
- D: uterus + cervix
- E: cul de sac cyst
- F: terminal ileum + cecum
- G: colon

Gross Description:

A total of seven specimens are received, each in separate containers. The first

[page 3 of 5]
container is labelled with the patient's name, MRN and OMENTUM. Within the container are four fragments of fibroadipose tissue, the largest measuring 25 cm x 22 cm x 1.5 cm. At one end of the omentum there is a solid nodular thickening with white parenchyma measures 7 x 6 x 2 cm and invading through the omental fat. The area has been sampled for research (). There are additional smaller nodules (more than fifteen, 1 cm in diameter and less) scattered throughout the remainder of the omentum. The smaller fragments aggregate to 5 x 5 x 1.5 cm. One of these smaller fragments appears to be entirely composed of tumour. Sections are submitted for histological analysis as follows:

- A1 -largest tumour nodule, representative section
- A2 -representative section of additional tumour nodules
- A3 -representative sections of omentum

The second container is labelled with the patient's name, MRN and R OVARY AND TUBE. Within the container is a right ovary (2.5 x cm 2.5 cm x 2 cm) and fallopian tube (3.5 cm in length). On sectioning, the ovary has three cystic areas, the largest measuring 2 cm x 1 cm x 1 cm, which contain white-maroon solid tissue. The fallopian tube is unremarkable. Sections are submitted for histological analysis as follows:

- B1-B2 -contiguous representative section of ovary
- B3 -representative sections of fallopian tube

The third container is labelled with the patient's name, MRN and LEFT OVARY AND TUBE. Within the container is an ovary (3 cm x 1.5 cm x 1.5 cm) and fallopian tube (3 cm in length). The ovary contains cysts similar to the right ovary. The tube has a paratubal cyst (1.5 cm x 1 cm x 0.7 cm). Sections are submitted for histological analysis as follows:

- C1 -left ovary, representative section
- C2-C3 -left fallopian tube, representative sections

The fourth container is labelled with the patient's name, MRN and UTERUS PLUS CERVIX. Within the container is a uterus (including cervix), measuring 9 cm superior to inferior x 7 cm left to right x 3.5 cm anterior to posterior. There is a 4 cm diameter subserosal mass in the area of the left anterior uterus adjacent to the cornu. The serosal surface of the uterus is rough and covered with numerous adhesions. On sectioning, the endocervical and endometrial canals are unremarkable. The mass is composed of white whorled parenchyma with focal cavitations and hemorrhage that is not circumscribed and blends with the adjacent myometrium. Sections are submitted for histological analysis as follows:

- D1-D3 -mass, representative sections
- D4-D5 -anterior endometrium with underlying myometrium and mass, representative contiguous section
- D6 -anterior endocervical canal, representative sagittal section

[page 4 of 5]
D7 -posterior endometrium with underlying myometrium,
representative sagittal section
D8 -anterior endocervical canal, representative sagittal section
D9 -cul-de-sac, representative sections

The fifth container is labelled with the patient's name, MRN and CUL-DE-SAC CYST. Within the container is a 1 cm diameter cyst with white-maroon translucent wall. The inner surface of the cyst is unremarkable. This specimen is submitted in toto for histological analysis as follows:

E1 -cul-de-sac cyst, in toto

The sixth container is labelled with the patient's name, MRN and TERMINAL ILEUM AND CECUM. Within the container is terminal ileum with cecum and appendix. The terminal ileum is adhered together and measures an estimated 30 cm in length x up to 3.5 cm in diameter. The free surface of the terminal ileum is covered with adhesions and numerous (>50) small white-yellow nodules (0.5 cm in diameter and less). There are similar adhesions and nodules on the surface of the inferior portion of the cecum. In areas, the terminal ileal wall is thickened (up to 1 cm).

The terminal ileum and cecum are patent, with stenosis (lumen diameter <0.2 cm) in the terminal ileum 5 cm from the ileocecal valve. The mucosa of the terminal ileum and cecum is unremarkable. Within the bowel wall of the terminal ileum there are white nodular areas and solitary nodules in the adjacent mesentery, mostly in the area of stenosis. The largest individual nodule is 2.5 cm x 1.2 cm x 1 cm. The lumen of the appendix appears filled with yellow and white tissue, which gives the impression of reduplication of the mucous membranes. Sections are submitted for histological analysis as follows:

F1 -cecal wall adjacent to distal resection margin
F2 -terminal ileal wall adjacent to proximal resection margin
F3-F5 -terminal ileum with tumour, representative sections
F6-F7 -tumour present in mesenteric fat adjacent to terminal ileum
F8-F9 -areas of adhesion between terminal ileum and cecum
F10 -cecal wall with serosal studding
F11 -cecal wall, additional section
F12-F16 -appendix, in toto
F17-F19 -pericecal lymph nodes, one per cassette (two in F19)
F20 -grossly uninvolved terminal ileal wall, representative section

The seventh and final container is labelled with the patient's name, MRN and COLON. Within the container is a 7 cm long x 3 cm diameter section of colon. To one end of the specimen there is a submucosal nodule measuring 4.5 cm along the long axis of the colon x 3 cm x 2 cm. The tumour is grossly evident at the mesenteric resection margin, which is inked black. The tumour itself is composed of nodular, homogenous white tissue that focally invades bowel wall. Sections are submitted for histological analysis as

[page 5 of 5]
follows:

G1 -bowel wall adjacent between surgical resection margin and tumour

G2 -bowel wall adjacent to opposite surgical margin

G3-G4 -tumour, representative sections

G5 -tumour invading bowel wall, representative sections

G6-G7 -nodules in pericolic fat, two per cassette

Source: NCI Genomic Data Commons file 1e1dc8f2-c66d-4979-876b-519cbe267e7f (TCGA-36-2540.D66D4750-20F9-4E75-BDB7-B48DE6DBC449.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).